Gene-level copy-number profile of tumor specimen TCGA-2Z-A9J3-01A from TCGA case TCGA-2Z-A9J3, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.4 years (24,626 days).
Specimen TCGA-2Z-A9J3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.f53b40ef-4583-40a3-9a1a-aeec38320ca3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Z-A9J3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/651cc869-eb8a-4741-a2b9-a3d704886c57

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,366; copy number 2: 43,868; copy number 3: 7,186; copy number 4: 2,168; copy number 5: 389; copy number 6: 2,841.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Z-A9J3-01A-12D-A381-01): tumor purity 0.9, ploidy 2.36, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,230 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:101,878,333–118,810,836, 201 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 5–6 (broad region; genes not listed).
- chr17:44,793,199–45,109,016, 15 genes, copy number 5 (within-gene range 3–5): AC005180.2, AC005180.1, GJC1, HIGD1B, EFTUD2, RN7SL405P, CCDC103, FAM187A, GFAP, KIF18B, MIR6783, AC015936.1, NMT1, C1QL1, AC015936.2.

Autosomal genes at a single copy (total copy number 1): 945. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
